Somatic mutation profile of tumor specimen 0DEHNY from CCDI case PBBPLH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Craniopharyngioma, adamantinomatous; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,476 days).
Specimen 0DEHNY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad0080a4-5220-44ad-986b-da9ea0d3e048.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEHN2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4e3cbd4-84af-4faf-ae83-1b83b08c1e52

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 177/525 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 24/542 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
